Somatic mutation profile of tumor specimen TCGA-BJ-A0ZC-01A (aliquot TCGA-BJ-A0ZC-01A-12D-A13W-08) from TCGA case TCGA-BJ-A0ZC, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.5 years (20,282 days).
Specimen TCGA-BJ-A0ZC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4a54f58-ce42-4d96-b46c-da5a3cb6646c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BJ-A0ZC-10A (Blood Derived Normal), aliquot TCGA-BJ-A0ZC-10A-01D-A13W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb0f65e7-ea0c-46f8-8093-697c396c8a02

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HIF3A | c.518C>T p.T173I (on ENST00000377670 / NM_152795.4; = p.T104I on NM_022462.4) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV52197972; called by muse, mutect2, varscan2
- ISM1 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1226583295, COSV99339789; called by muse, mutect2
- PIK3R5 | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.062); catalogued as COSV52653343; called by muse, mutect2, varscan2
- ULK3 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- FOXQ1 | c.405G>T p.S135= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV57258853; called by muse, mutect2
- H4C13 | c.264T>A p.V88= | Silent (SNP) | VAF 41/97 reads (42%) | catalogued as COSV60693940; called by muse, mutect2, varscan2
- RBPMS | c.360G>A p.L120= | Silent (SNP) | VAF 14/156 reads (9%) | catalogued as COSV55122822; called by muse, mutect2
- PLOD1 | c.741+130C>G | Intron (SNP) | VAF 8/191 reads (4%) | called by muse, mutect2
